Somatic mutation profile of tumor specimen TCGA-DD-A1EL-01A (aliquot TCGA-DD-A1EL-01A-11D-A152-10) from TCGA case TCGA-DD-A1EL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 23.5 years (8,573 days).
Specimen TCGA-DD-A1EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 811ee895-e06e-46e2-880a-d39c4dfaf240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EL-10A (Blood Derived Normal), aliquot TCGA-DD-A1EL-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7aad6fb-dc65-476e-86cf-04e3e999956f

The open-access MAF lists 109 somatic variants for this specimen: 78 protein-altering or splice-affecting, 23 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 23, 3'UTR 5, Nonsense Mutation 4, Splice Site 2, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 1, RNA 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.107A>C p.H36P | Missense Mutation (SNP) | VAF 49/124 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV62688989, COSV62691224; called by muse, mutect2, varscan2
- TP53 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 34/50 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52660939, COSV52789715, COSV53470581; called by muse, mutect2, varscan2
- ADIPOR1 | c.190G>T p.V64L | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61851489; called by muse, mutect2, varscan2
- AGBL3 | c.484delinsTA p.V162Yfs*5 | Frame Shift Ins (INS) | VAF 40/104 reads (38%) | catalogued as COSV51951966; called by mutect2*, pindel, varscan2*
- AMER1 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57660399; called by muse, mutect2, varscan2
- ARHGEF6 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 94/109 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51690345, COSV51697349, COSV99166339; called by muse, mutect2, varscan2
- ASAH2 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 167/316 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.428); catalogued as COSV61483297; called by muse, mutect2, varscan2
- ATG13 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs780215956; called by muse, varscan2
- ATP6V0A1 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 250/646 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV52873253; called by muse, mutect2, varscan2
- C12orf4 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV54206898; called by muse, mutect2, varscan2
- CCDC43 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 145/368 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59519866; called by muse, mutect2, varscan2
- CEACAM18 | c.656T>G p.I219S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV67282780; called by muse, mutect2, varscan2
- CGB2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV56819978; called by muse, mutect2, varscan2
- CHRNA4 | c.1646G>C p.R549P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV64719403; called by muse, mutect2
- CLSTN2 | c.2082A>T p.L694F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71720717; called by muse, mutect2, varscan2
- COPA | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54102114, COSV99614766; called by muse, mutect2, varscan2
- CSH1 | c.625C>A p.R209S | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61764004, COSV60241761, COSV60242172; called by muse, mutect2, varscan2
- CTNND2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58887275, COSV58888791; called by muse, mutect2, varscan2
- DCHS1 | c.9578G>T p.C3193F | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.452); catalogued as rs1465045788, COSV54997342; called by muse, mutect2, varscan2
- DENND4B | c.1056G>C p.A352= | Splice Region (SNP) | VAF 45/84 reads (54%) | catalogued as COSV63409077; called by muse, mutect2, varscan2
- DMXL2 | c.3832G>C p.V1278L | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV51846025, COSV51850660; called by muse, mutect2, varscan2
- DNAH10 | c.3901G>T p.A1301S (on ENST00000409039; = p.A1240S on NM_207437.3) | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.181); catalogued as COSV68987370, COSV68993353; called by muse, mutect2, varscan2
- DNAH8 | c.1483A>T p.K495* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV59443847; called by muse, mutect2, varscan2
- DNAJC8 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV55281489; called by muse, mutect2, varscan2
- ESRRA | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50005514; called by muse, mutect2, varscan2
- FBN3 | c.3172G>T p.G1058C | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54459992; called by muse, mutect2, varscan2
- FLOT2 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777162321, COSV67529033; called by muse, mutect2, varscan2
- GAPDHS | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV55880462; called by muse, mutect2, varscan2
- GPR158 | c.1983G>T p.L661F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66269642; called by muse, mutect2, varscan2
- IQUB | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1450165298, COSV100227507, COSV61239118; called by muse, mutect2, varscan2
- IRAG2 | c.3612C>A p.S1204R (on ENST00000636465; = p.S249R on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV63138704; called by muse, mutect2, varscan2
- KCTD8 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as COSV63588875; called by muse, mutect2, varscan2
- KDM5B | c.3635G>T p.G1212V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV52507464; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIF13A | c.5392G>T p.A1798S | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52450562; called by muse, mutect2, varscan2
- KIF21B | c.4307G>T p.R1436L (on ENST00000422435 / NM_001252100.2; = p.R1423L on NM_017596.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59754349, COSV59757361; called by muse, mutect2, varscan2
- KRTAP10-1 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59961405; called by muse, mutect2, varscan2
- KRTAP3-3 | c.60C>A p.C20* | Nonsense Mutation (SNP) | VAF 84/232 reads (36%) | catalogued as COSV66956640; called by muse, varscan2
- LGALS7 | c.96G>C p.R32S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV101068614; called by muse, mutect2, varscan2
- LRIG2 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 60/148 reads (41%) | catalogued as COSV63162013; called by muse, mutect2, varscan2
- MAGEB18 | c.500T>A p.V167E | Missense Mutation (SNP) | VAF 72/81 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57463938; called by muse, varscan2
- MAGI3 | c.1018+2T>C p.X340_splice | Splice Site (SNP) | VAF 12/221 reads (5%) | catalogued as COSV56834837; called by muse, mutect2
- MYADML2 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs931530655, COSV57999218; called by muse, mutect2, varscan2
- MYOD1 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1177547598, COSV51453634; called by muse, mutect2
- NT5DC1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126375, COSV60308607; called by muse, mutect2, varscan2
- OBSCN | c.9514G>T p.A3172S | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as COSV52772084; called by muse, mutect2, varscan2
- OR2G2 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 133/445 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740444; called by muse, mutect2, varscan2
- PCDH17 | c.2720G>A p.G907D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1208260199, COSV64973859, COSV64975446; called by muse, mutect2, varscan2
- PCDHGB7 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53943949; called by muse, mutect2, varscan2
- PCGF2 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1196536292; called by muse, mutect2, varscan2
- PHACTR4 | c.1353C>G p.S451R (on ENST00000373839 / NM_001350159.2; = p.S461R on NM_023923.4) | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV65783904; called by muse, mutect2, varscan2
- PLXND1 | c.5072G>A p.R1691Q | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs201100072, COSV60713019; called by muse, mutect2, varscan2
- PPFIA2 | c.1943C>A p.T648K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61031297, COSV61061302; called by muse, mutect2, varscan2
- PRPF40A | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV58442763; called by muse, mutect2, varscan2
- PRXL2B | c.643C>G p.P215A (on ENST00000444521; = p.P167A on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.365); catalogued as COSV56521349, COSV99983336; called by muse, mutect2, varscan2
- RANBP2 | c.3323G>T p.G1108V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV51700863; called by muse, mutect2, varscan2
- REEP5 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV54841942; called by muse, mutect2, varscan2
- RNASEH2C | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as CM102544, COSV57729564; called by muse, mutect2, varscan2
- ROBO2 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs751528165, COSV59905197; called by muse, mutect2, varscan2
- SELENOP | c.534+1G>T p.X178_splice | Splice Site (SNP) | VAF 101/297 reads (34%) | catalogued as COSV62792450; called by muse, mutect2, varscan2
- SNRPA1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54257638; called by muse, mutect2, varscan2
- SP6 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); catalogued as COSV60617447; called by muse, mutect2, varscan2
- SPATA31D1 | c.3810G>T p.Q1270H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61195523; called by muse, mutect2, varscan2
- STOML1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV57551565; called by muse, mutect2, varscan2
- SYF2 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52573459; called by muse, mutect2, varscan2
- TGFBRAP1 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV51512013; called by muse, mutect2, varscan2
- TNNI3K | c.2206A>T p.S736C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.993); catalogued as COSV53948221; called by muse, mutect2, varscan2
- TNS2 | c.215A>T p.E72V (on ENST00000314250 / NM_170754.4; = p.E82V on NM_015319.2) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV58577312; called by muse, mutect2, varscan2
- ZBTB18 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 79/96 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62396906; called by muse, mutect2, varscan2
- ZNF423 | c.1788C>A p.H596Q (on ENST00000563137 / NM_001379286.1; = p.H588Q on NM_015069.4) | Missense Mutation (SNP) | VAF 146/406 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52187785; called by muse, mutect2, varscan2
- AGBL3 | c.483dup p.V162Cfs*5 | Frame Shift Ins (INS) | VAF 36/72 reads (50%) | called by mutect2, varscan2
- AUP1 | c.690del p.R231Afs*3 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- DVL1 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIR3DL2 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP4-16 | c.387C>A p.C129* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | called by muse, mutect2, varscan2
- OR5D14 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D14 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- RSU1P1 | n.241C>A | Splice Region (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- ABCB6 | c.1182G>T p.T394= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV54695751; called by muse, mutect2, varscan2
- BPIFB4 | c.732C>T p.G244= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs772317789, COSV64951160; called by muse, mutect2, varscan2
- CACNA1B | c.4461G>C p.V1487= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV53125254; called by muse, mutect2, varscan2
- COL11A2 | c.1983G>T p.G661= (on ENST00000341947 / NM_080680.3; = p.G554= on NM_080679.2) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV59496682; called by muse, mutect2, varscan2
- DOCK3 | c.4995C>T p.T1665= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56520270; called by muse, varscan2
- HPN | c.1059C>T p.S353= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as rs1227466391, COSV52883532; called by muse, mutect2, varscan2
- IGKV2D-24 | c.324C>A p.V108= | Silent (SNP) | VAF 46/220 reads (21%) | called by muse, varscan2
- KATNAL2 | c.1269C>A p.P423= (on ENST00000356157 / NM_001353899.1; = p.P351= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV55298806; called by muse, mutect2, varscan2
- KLHL31 | c.1209C>A p.A403= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV63881799; called by muse, mutect2, varscan2
- LRG1 | c.546G>T p.G182= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV56703636; called by muse, mutect2, varscan2
- MEGF6 | c.876G>T p.G292= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as COSV53889563; called by muse, mutect2, varscan2
- MPP4 | c.150G>A p.V50= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs201304506, COSV59630942; called by muse, mutect2, varscan2
- NPHS1 | c.627A>T p.S209= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV62287716; called by muse, mutect2, varscan2
- OSER1 | c.363G>T p.L121= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV54853685; called by muse, mutect2, varscan2
- PCARE | c.2691C>T p.T897= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs767685634, COSV59054838; called by muse, mutect2, varscan2
- PCYT2 | c.552G>T p.R184= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV58711252; called by muse, mutect2, varscan2
- RUNDC1 | c.1509T>A p.P503= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV64511820; called by muse, mutect2, varscan2
- SNX7 | c.1161G>C p.V387= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV60268245; called by muse, mutect2, varscan2
- TAF4 | c.2481G>T p.S827= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV53337475; called by muse, mutect2, varscan2
- TRAK2 | c.1708C>T p.L570= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV60271931; called by muse, mutect2, varscan2
- TRIP12 | c.2895C>T p.A965= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV52263649; called by muse, mutect2, varscan2
- TTC23 | c.369G>T p.V123= | Silent (SNP) | VAF 89/150 reads (59%) | catalogued as COSV50441783; called by muse, mutect2, varscan2
- UNC93A | c.156G>A p.L52= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs558415122, COSV57808432; called by muse, mutect2, varscan2
- CSNK1A1L | c.-270C>A | 5'UTR (SNP) | VAF 10/31 reads (32%) | catalogued as COSV101131070, COSV101131110; called by muse, mutect2, varscan2
- DDI1 | c.*1035G>T | 3'UTR (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100158036; called by muse, mutect2
- FUT9 | c.*10139G>T | 3'UTR (SNP) | VAF 61/174 reads (35%) | catalogued as COSV100133159; called by muse, mutect2, varscan2
- LCE1B | c.*186T>C | 3'UTR (SNP) | VAF 79/283 reads (28%) | catalogued as COSV100780256; called by muse, mutect2, varscan2
- MMP19 | chr12:55834917 G>A | 3'Flank (SNP) | VAF 63/138 reads (46%) | catalogued as rs985044952; called by muse, mutect2, varscan2
- TENT5C | c.*3605G>T | 3'UTR (SNP) | VAF 43/137 reads (31%) | catalogued as COSV101032809; called by muse, mutect2, varscan2
- TSKU | c.*652A>G | 3'UTR (SNP) | VAF 29/68 reads (43%) | catalogued as rs1047501803, COSV100289968; called by muse, mutect2, varscan2
- ZNF192P1 | n.758G>T | RNA (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
